Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4QQ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4QQ-01A (Primary Tumor).

Gross Description: Lung of 15x13x14 cm in size. The tumor is located near the bronchus up to 4 ?m in size, grey-whitish coloured, dense.

Microscopic Description: Squamous carcinoma of the lung, G1, keratinizing type. Two subcarinal lymph nodes demonstrated anthracosis.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 0 x 0 x 4 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/2 positive for metastasis (Subcarinal lymph nodes 0/2)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- lower

ICD-0-3
carcinoma, squamous cell, Keratinizing, NOS
8071/3
Site: lung, (R) lower lobe C34.3
10/23/12

Reviewed Initials:	KMI	10/15/12

Source: NCI Genomic Data Commons file bd247526-8ec1-48a8-a9e9-f8c002d2e2a6 (TCGA-85-A4QQ.5265DA24-3D23-4CEA-9F1B-B7820BF83237.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).